Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADP-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo : -

GROSS:

Specimen status: Fresh

Specimen:

Liver: 18.0 x 8.0 x 5.5 cm, 235.0 gm

Gallbladder: 10.5 cm in length, 3.0 cm in diameter, 0.2 cm in wall thickness

Operation: Partial hepatectomy and cholecystectomy

[Liver]

Lesion:

A well-defined mass (2.2 x 1.5 x 1.5 cm) with extensive portal vein invasion

Cut surface: Yellowish tan and solid

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 0.2 cm)

Others: Satellite nodule: No

Remaining parenchyma: Cirrhotic

Portal vein invasion: Yes

Gross photo: Present

Blocks

T1-2 and TB, tumor x 3

T3-5, tumor with portal vein invasion x 3

RM, tumor with resection margin x 1

NB and L, remaining liver x 2

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma

Edmondson-Steiner grade

The worst grade III

The major grade III

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion:

No, but close margin of the clearance (less than 0.1 cm)

Serosal invasion: No

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

QD 5/20/14

[page 2 of 2]
Portal vein invasion: Yes
Microvessel invasion: Yes
Intrahepatic metastasis: No
Multicentric occurrence: No

NOT reported. Gross:

Stomach, body, scopic, chronic gastritis, H. pylori, associated

Liver, ectomy, Hepatocellular carcinoma
T56000, P10, M81703
Gallbladder, ectomy, Chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, partial hepatectomy: Hepatocellular carcinoma
Gallbladder, cholecystectomy: Chronic cholecystitis
Suggestion :

Source: NCI Genomic Data Commons file 3b02531c-f8ca-42c1-bbdb-7779464da919 (TCGA-DD-AADP.11B44F97-2332-4CB7-B57C-063B1C6127EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).